Somatic mutation profile of tumor specimen 0DKWNB from CCDI case PBBYVY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.5 years (534 days).
Specimen 0DKWNB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5d20a7b-3eee-460a-82ee-9b3e3395e5e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKWNR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38871f1e-9c59-47c8-b819-15c08d687f09

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAAF2 | c.7A>T p.K3* | Nonsense Mutation (SNP) | VAF 116/249 reads (47%) | called by muse, mutect2, varscan2
- THEMIS2 | c.1772C>T p.A591V (on ENST00000373921 / NM_001286115.1; = p.G233= on NM_004848.3) | Missense Mutation (SNP) | VAF 222/527 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- HPS3 | c.2457A>G p.T819= | Silent (SNP) | VAF 55/389 reads (14%) | called by muse, mutect2, varscan2
- LARP1B | c.807C>T p.I269= | Silent (SNP) | VAF 69/732 reads (9%) | catalogued as rs1229525780; called by muse, mutect2, varscan2
- PCYT1A | c.855C>T p.F285= | Silent (SNP) | VAF 227/510 reads (45%) | catalogued as COSV53056090; called by muse, mutect2, varscan2
- CCDC146 | c.2278-25C>A | Intron (SNP) | VAF 40/232 reads (17%) | called by mutect2, varscan2
